Gene-level copy-number profile of tumor specimen TARGET-40-0A4HLD-01A from TARGET case TARGET-40-0A4HLD, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 19.9 years (7,254 days).
Specimen TARGET-40-0A4HLD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.1e3986d0-3fea-52ac-b168-7cedfbb497c0.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4HLD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 427 have no estimate.
https://portal.gdc.cancer.gov/files/3ebfcdbe-adfa-4c7e-a5c5-5472f6df8dcc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 329; copy number 1: 2,811; copy number 2: 26,406; copy number 3: 16,411; copy number 4: 7,257; copy number 5: 5,325; copy number 6: 1,045; copy number 7: 191; copy number 8: 272; copy number 9: 83; copy number 10: 22; copy number 12: 44.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.
- chr13:48,340,797–48,341,330, 1 gene: AL392048.1.
- chr13:48,653,711–48,771,827, 2 genes (within-gene range 0–2): CYSLTR2, PSME2P2.
- chr13:93,818,424–93,836,144, 1 gene: GPC6-AS2.
- chr13:107,788,342–107,835,451, 1 gene (within-gene range 0–3): FAM155A-IT1.
- chr13:108,207,439–108,448,316, 6 genes (within-gene range 0–1): LIG4, ABHD13, TNFSF13B, AL157762.1, RNA5SP39, AL138694.1.
- chr13:109,163,902–109,201,483, 1 gene (within-gene range 0–6): MYO16-AS1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,892 genes in 58 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,976,133–40,423,326, 1,091 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:68,375,327–71,047,808, 36 genes, copy number 9–10 (within-gene range 4–10): ELOCP18, AL139413.1, RPE65, DEPDC1, AL138789.1, DEPDC1-AS1, TXNP2, AL035412.1, AL033530.1, AL691520.1, LINC01707, LINC02791, LINC01758, AL359894.1, LRRC7, SGO1P1, AL117353.1, RN7SL538P, PIN1P1, LRRC7-AS1, LRRC40, RN7SL242P, SRSF11, AL353771.1, ANKRD13C, HHLA3, HHLA3-AS1, CTH, Metazoa_SRP, AL354872.1, CHORDC1P5, CASP3P1, LINC01788, AL513285.1, PTGER3, AL031429.1.
- chr1:72,636,547–79,282,124, 95 genes, copy number 6–12 (broad region; genes not listed).
- chr1:79,967,733–80,464,718, 8 genes, copy number 9: AC099671.1, AC098657.1, AC098657.2, AC098657.3, HMGB1P18, AL606519.1, HNRNPA1P64, AL596276.1.
- chr1:84,244,334–92,961,522, 164 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr1:101,270,875–102,389,630, 10 genes, copy number 5: PPIAP7, LINC01307, LINC01709, RNU6-965P, RPSAP19, OLFM3, RNU6-352P, AL356280.1, DNAJA1P5, AC114485.1.
- chr1:143,541,768–152,580,516, 362 genes, copy number 5 (broad region; genes not listed).
- chr1:152,613,811–209,567,673, 1,373 genes, copy number 5–6 (broad region; genes not listed).
- chr2:44,361,947–49,888,986, 99 genes, copy number 5–6 (broad region; genes not listed).
- chr2:82,268,427–83,523,502, 13 genes, copy number 6: LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809.
- chr2:88,691,673–89,969,335, 73 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr4:155,442,650–170,814,548, 193 genes, copy number 6–7 (broad region; genes not listed).
- chr5:16,941,843–26,749,997, 129 genes, copy number 5 (broad region; genes not listed).
- chr5:140,726,158–142,154,440, 110 genes, copy number 6 (broad region; genes not listed).
- chr5:143,277,931–145,230,054, 22 genes, copy number 6 (within-gene range 4–6): NR3C1, RPL7P21, AC091925.2, AC091925.1, AC016598.1, AC016598.2, RNU7-156P, AC008696.2, MIR5197, AC008696.1, HMHB1, RN7SL87P, YIPF5, KCTD16, AC008652.1, AC109441.1, CKS1BP5, AC008716.1, RN7SKP246, AC132803.1, NAMPTP2, ASS1P10.
- chr5:148,826,611–151,924,851, 98 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr6:62,460,940–66,094,909, 30 genes, copy number 6–7: DHFRP5, AL355375.1, AL355375.2, AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1.
- chr6:121,435,595–123,072,925, 27 genes, copy number 5: GJA1, RNU4-35P, AL138729.1, RNU4-76P, RNU2-8P, AL603865.2, SLC25A5P7, RPL23AP48, AL603865.1, HMGB3P18, RNU1-18P, HSF2, Z99129.4, SERINC1, Z99129.1, PKIB, Z99129.3, Z99129.2, AL512283.2, AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A, ATP5MGP2, AL591428.1, CLVS2.
- chr6:130,827,406–133,532,128, 60 genes, copy number 5 (within-gene range 4–5): SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, AL513524.1, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1, RBM11P1, SLC18B1, RPS12, SNORD101, SNORD100, SNORA33, HMGB1P13, AL137783.1, LINC00326, RPL23AP46, AL591115.1, MTCYBP4, EYA4, AL024497.1, AL024497.2.
- chr6:149,027,700–170,738,536, 403 genes, copy number 5–6 (broad region; genes not listed).
- chr7:57,270,839–62,275,678, 31 genes, copy number 5: AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr7:92,412,550–92,836,573, 13 genes, copy number 7 (within-gene range 3–7): TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P.
- chr8:142,657,460–143,160,711, 28 genes, copy number 5: JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1, LY6D, AC083841.2, AC083841.4, AC083841.3, GML, ZNHIT1P1, CYP11B1, CYP11B2, LY6E-DT, CDC42P3, LY6E, C8orf31, AK3P2, AC083982.1, LY6L, LY6H.
- chr11:29,980,113–31,369,810, 12 genes, copy number 7 (within-gene range 3–7): LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1.
- chr11:46,376,402–48,433,147, 75 genes, copy number 6 (broad region; genes not listed).
- chr12:2,603,350–3,371,346, 34 genes, copy number 5: CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1, ITFG2-AS1, AC092471.2, LINC02371, IQSEC3P1, AC092471.1, RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417.
- chr12:33,717,853–34,249,958, 13 genes, copy number 6: AC024153.1, RNU6-472P, Y_RNA, AC046130.1, ALG10, AC046130.2, AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1.
- chr13:94,025,470–105,797,539, 165 genes, copy number 5–9 (broad region; genes not listed).
- chr13:109,269,634–114,337,626, 118 genes, copy number 6 (broad region; genes not listed).
- chr14:25,124,467–28,613,623, 26 genes, copy number 5: LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171, BNIP3P1, AL139023.1, RPL26P3, LINC02300, EIF4A1P12.
- chr14:40,630,006–49,077,505, 74 genes, copy number 5 (broad region; genes not listed).
- chr14:52,951,432–67,816,590, 288 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr14:68,605,396–93,976,739, 475 genes, copy number 5–6 (broad region; genes not listed).
- chr14:94,430,633–101,563,452, 268 genes, copy number 5–6 (broad region; genes not listed).
- chr14:104,085,686–106,443,583, 189 genes, copy number 5–6 (broad region; genes not listed).
- chr18:36,777,647–41,632,185, 32 genes, copy number 5–6: TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6.
- chr18:50,457,887–54,895,516, 46 genes, copy number 5 (within-gene range 4–5): RPLP0P11, MAPK4, AC012433.2, AC012433.1, MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1, DCC, AC011155.1, VN1R76P, MIR4528, LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57.
- chr21:31,840,341–36,990,236, 124 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr22:16,572,027–23,164,350, 431 genes, copy number 5–9 (broad region; genes not listed).
- chr22:25,279,529–25,520,854, 13 genes, copy number 9: AL022332.1, AL022324.4, AL022332.2, IGLL3P, AL022324.1, AL022324.2, LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Autosomal genes at a single copy (total copy number 1): 1,966. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
